Somatic mutation profile of tumor specimen TCGA-CV-7090-01A (aliquot TCGA-CV-7090-01A-11D-2012-08) from TCGA case TCGA-CV-7090, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 39.7 years (14,515 days).
Specimen TCGA-CV-7090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81bbc5a7-08b4-4952-bc07-7791c070e58a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7090-10A (Blood Derived Normal), aliquot TCGA-CV-7090-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ea1de44-85fc-4558-93f2-9185e7f12659

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 17, Nonsense Mutation 4, Frame Shift Ins 2, Intron 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- HPRT1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs387906725, CM920351, COSV100053047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1782+1G>A p.X594_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99558671; called by muse, mutect2, varscan2
- ACE | c.3061G>A p.V1021M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as rs764129854, COSV99326411; called by mutect2, varscan2
- ADAP2 | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV100437148; called by muse, mutect2, varscan2
- AFAP1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100631101; called by muse, mutect2, varscan2
- AGXT2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51490520; called by muse, mutect2, varscan2
- BAG4 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as COSV99781706; called by muse, mutect2
- BCAM | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.578); catalogued as rs778105866, COSV99538477; called by muse, mutect2, varscan2
- CHST8 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52864183; called by muse, mutect2, varscan2
- COL14A1 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901427317, COSV52849813, COSV52852703; called by muse, mutect2, varscan2
- CYP2J2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as rs750655796, COSV64606648; called by muse, mutect2, varscan2
- DIAPH3 | c.881C>T p.A294V (on ENST00000400324 / NM_001042517.2; = p.A31V on NM_030932.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs760380418, COSV99932751; called by mutect2, varscan2
- FAT3 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV99961810; called by muse, mutect2, varscan2
- FGB | c.799A>T p.R267* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV100122313; called by muse, mutect2
- GABRB3 | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV100158168; called by muse, mutect2, varscan2
- GRK3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs200558027; called by mutect2, varscan2
- GRM8 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1397461316, COSV58849727; called by muse, mutect2, varscan2
- LRIF1 | c.248A>C p.Q83P | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV100870795, COSV63897343; called by muse, mutect2, varscan2
- MADD | c.2035C>A p.Q679K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as COSV100211035; called by muse, mutect2, varscan2
- MAP10 | c.220dup p.T74Nfs*14 | Frame Shift Ins (INS) | VAF 37/132 reads (28%) | catalogued as rs1459030787; called by mutect2, pindel, varscan2
- METTL15 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs564068143, COSV100327862; called by muse, mutect2, varscan2
- NT5C3A | c.616G>C p.E206Q (on ENST00000610140 / NM_001374335.1; = p.E172Q on NM_016489.13) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54239735; called by muse, mutect2, varscan2
- NUMA1 | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs745630935, COSV99474481; called by muse, mutect2, varscan2
- ODF1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs538680193, COSV99574003; called by muse, mutect2, varscan2
- PATJ | c.5153C>T p.T1718I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100956141; called by muse, mutect2, varscan2
- PLCD1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs576674144, COSV100587335; called by mutect2, varscan2
- TJP2 | c.1948A>T p.I650F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99600556; called by muse, mutect2, varscan2
- TUBD1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV99847322; called by muse, mutect2, varscan2
- UNC79 | c.3719C>T p.A1240V (on ENST00000393151 / NM_001346218.2; = p.A1063V on NM_020818.5) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs750556895, COSV56395989, COSV99825398; called by muse, mutect2, varscan2
- ZNF146 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.993); catalogued as COSV100757633; called by muse, mutect2
- ZNF480 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.485); catalogued as rs746046422, COSV57996869; called by muse, mutect2, varscan2
- RUNX1 | c.883dup p.S295Ffs*278 (on ENST00000344691 / NM_001001890.3; = p.S322Ffs*278 on NM_001754.5) | Frame Shift Ins (INS) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- TSSK4 | c.-1_15del | Translation Start Site (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel
- ABCB5 | c.1942C>T p.L648= (on ENST00000404938 / NM_001163941.2; = p.L203= on NM_178559.6) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99327375; called by muse, mutect2, varscan2
- AC092143.1 | c.1542C>T p.F514= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs757357850, COSV100205588; called by muse, mutect2, varscan2
- ARID1A | c.3429G>C p.G1143= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100250284, COSV99055273; called by muse, mutect2, varscan2
- BBS9 | c.1527C>G p.S509= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99625935; called by muse, mutect2
- CABLES1 | c.1731C>G p.L577= (on ENST00000256925 / NM_001100619.2; = p.L312= on NM_138375.2) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99908296; called by muse, mutect2
- CADM2 | c.1050C>A p.T350= (on ENST00000407528 / NM_001167674.2; = p.T352= on NM_153184.4) | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as COSV101052787; called by muse, mutect2, varscan2
- CCDC183 | c.1119C>T p.S373= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1248216824, COSV100272808; called by muse, mutect2, varscan2
- EPG5 | c.4140G>T p.L1380= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99956468; called by muse, mutect2, varscan2
- EYA4 | c.654C>A p.G218= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100765178; called by muse, mutect2, varscan2
- IFT80 | c.1068C>T p.Y356= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs774425025, COSV100424368, COSV58453136; called by muse, mutect2, varscan2
- PAK5 | c.1401C>T p.T467= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs368434501, COSV62025536; called by muse, mutect2, varscan2
- PTPRB | c.1809T>C p.S603= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99715714; called by muse, mutect2, varscan2
- SECISBP2L | c.72G>A p.K24= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99959841; called by muse, mutect2, varscan2
- TBX22 | c.750C>A p.S250= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV100960607, COSV100960769; called by muse, mutect2, varscan2
- TYK2 | c.705G>C p.R235= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99314220; called by muse, mutect2
- ZNF112 | c.420C>T p.L140= (on ENST00000337401 / NM_001083335.2; = p.L134= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs147887844; called by muse, mutect2, varscan2
- ZNF141 | c.933C>T p.Y311= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs1241068596, COSV99549384; called by muse, mutect2, varscan2
- CREM | c.121-8107T>G | Intron (SNP) | VAF 23/97 reads (24%) | catalogued as COSV100414964; called by muse, mutect2, varscan2
